Gene-level copy-number profile of tumor specimen TCGA-B5-A5OD-01A from TCGA case TCGA-B5-A5OD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.8 years (24,775 days).
Specimen TCGA-B5-A5OD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.044c938b-35f5-48eb-8edc-345608583259.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A5OD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb6651f8-29d9-4b0b-8e8d-29936a5b2658

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 2,694; copy number 2: 14,149; copy number 3: 22,830; copy number 4: 14,232; copy number 5: 3,165; copy number 6: 2,132; copy number 7: 277; copy number 8: 215; copy number 9: 85; copy number 10: 2; copy number 11: 13; copy number 12: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B5-A5OD-01A-11D-A31T-01): tumor purity 0.72, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,591,969, 5 genes: LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 602 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,464,330–66,038,834, 62 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr3:75,182,754–77,649,964, 35 genes, copy number 8 (within-gene range 3–8): RN7SL294P, MIR4444-2, AC117481.1, HNRNPA3P6, MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26, LINC00960, ZNF717, MIR4273, ROBO2, Y_RNA, CAP1P1.
- chr3:162,486,541–174,378,005, 146 genes, copy number 7–8 (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 8: RN7SKP40.
- chr4:146,214,515–146,642,474, 7 genes, copy number 7 (within-gene range 4–7): REELD1, AC097372.3, AC097372.1, SLC10A7, MIR7849, RNU1-44P, POU4F2.
- chr6:31,620,715–32,115,334, 64 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr6:36,639,545–36,928,964, 13 genes, copy number 7: RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2, Z85996.3, PPIL1, C6orf89.
- chr6:73,353,063–73,570,596, 14 genes, copy number 7: DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1.
- chr12:66,767–991,190, 25 genes, copy number 9: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr12:1,151,810–1,153,059, 1 gene, copy number 9: HTR1DP1.
- chr12:5,948,877–7,479,897, 91 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:38,078,529–41,932,592, 48 genes, copy number 9–12 (within-gene range 6–12): AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1.
- chr19:29,775,504–33,773,509, 82 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr20:35,302,566–35,621,094, 13 genes, copy number 11 (within-gene range 6–11): UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4.

Autosomal genes at a single copy (total copy number 1): 1,531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
